Gene-level copy-number profile of tumor specimen HCM-BROD-0213-C71-02A from HCMI case HCM-BROD-0213-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.3 years (21,286 days).
Specimen HCM-BROD-0213-C71-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 072575e9-ed1e-47da-9ca0-55c86a391cb9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0213-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,244 have no estimate.
https://portal.gdc.cancer.gov/files/c305fa65-f08c-4b85-aefd-685d305d5b10

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 81; copy number 1: 4,472; copy number 2: 49,646; copy number 3: 3,837; copy number 4: 219; copy number 5: 79; copy number 14: 10; copy number 15: 1; copy number 20: 1; copy number 36: 3; copy number 37: 28; copy number 38: 2.

Homozygous deletions (total copy number 0; autosomes only): 81 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,705,338–23,438,700, 76 genes (within-gene range 0–1) (broad region; genes not listed).
- chr9:61,665,579–61,666,386, 1 gene: AL935212.2.
- chr9:64,473,040–64,498,745, 4 genes: CR769776.1, CNN2P3, GXYLT1P6, AL773524.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 124 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:54,132,686–54,200,073, 1 gene, copy number 5 (within-gene range 2–5): AL357673.1.
- chr1:54,169,651–55,324,691, 32 genes, copy number 5: CYB5RL, MRPL37, SSBP3, SSBP3-AS1, AL161644.1, AL035415.1, AC099796.2, LINC02784, AC099796.1, HNRNPA1P63, ACOT11, FAM151A, AL590093.1, MROH7, MROH7-TTC4, TTC4, PARS2, TTC22, AC096536.1, LEXM, DHCR24, AC096536.3, AC096536.2, DHCR24-DT, TMEM61, AL590440.1, BSND, PCSK9, USP24, MIR4422HG, GYG1P3, MIR4422.
- chr1:55,367,466–55,398,620, 4 genes, copy number 5: GOT2P1, MTCO2P34, RN7SKP291, RNU6-830P.
- chr6:34,696,317–36,024,868, 42 genes, copy number 5 (within-gene range 2–5): AL451165.2, AL451165.1, AL139100.1, SNRPC, UHRF1BP1, Y_RNA, RNY3P15, TAF11, ANKS1A, HSPE1P11, AL591002.1, AL138721.1, TCP11, SCUBE3, Z97832.2, ZNF76, Z97832.1, DEF6, PPARD, MKRN6P, FANCE, RPL10A, MIR7111, TEAD3, TULP1, AL033519.4, AL033519.3, FKBP5, AL033519.2, AL033519.5, AL033519.1, MIR5690, AL157823.2, ARMC12, AL157823.1, CLPSL2, CLPSL1, CLPS, LHFPL5, SRPK1, SLC26A8, DPRXP2.
- chr7:54,556,970–55,743,457, 28 genes, copy number 37 (within-gene range 3–37): VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2.
- chr7:65,773,620–65,814,775, 2 genes, copy number 14–20: GTF2IP5, RNU6-912P.
- chr20:19,756,390–20,712,644, 15 genes, copy number 14–38: AL121761.1, RIN2, RPL12P12, NAA20, CRNKL1, CFAP61, AL035454.1, AL049648.1, RPL17P1, CFAP61-AS1, RN7SL690P, AL161658.1, INSM1, RALGAPA2, EIF4E2P1.

Autosomal genes at a single copy (total copy number 1): 4,472. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
